Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4QI, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4QI-01A (Primary Tumor).

Gross Description: There is a stomach with saucer-like tumor up to 6x4 cm in size, which circularly narrows the lumen of the stomach. Invasion is into the perigastric fat. Lymph nodes along the lesser curvature are not clearly detected. Lymph nodes of the greater curvature are suspicious of metastases. Omentum is hyperemic.

Microscopic Description: Adenocarcinoma of the stomach, G-3, with superficial ulceration, invasion into the perigastric fatty tissue. Examined lymph nodes of the greater and lesser curvature demonstrated reactive follicular hyperplasia, sinus histiocytosis. Omentum is hyperemic.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Antrum

Tumor size: 6 x 0 x 4 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Other - Perigastric fat

Lymph nodes: 0/10 positive for metastasis (Greater and lesser curvature 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

1C5-0-3
adenocarcinoma, NOS 8140/3
Site: stomach, antrum C16.3

hu
10/23/12

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

IIFAA Discrepancy		

Source: NCI Genomic Data Commons file 32affc24-4d46-4d6d-9abe-687ca7073595 (TCGA-BR-A4QI.0913A809-96C6-4AD2-90BD-8D53632AC727.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).